Somatic mutation profile of tumor specimen TCGA-CA-6716-01A (aliquot TCGA-CA-6716-01A-11D-1835-10) from TCGA case TCGA-CA-6716, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.6 years (23,943 days).
Specimen TCGA-CA-6716-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 999494ec-f78c-4001-a8cd-7d969bceafc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CA-6716-10A (Blood Derived Normal), aliquot TCGA-CA-6716-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d5f1f85-2ded-4b3d-8ea4-3029570d9bbf

The open-access MAF lists 169 somatic variants for this specimen: 118 protein-altering or splice-affecting, 48 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 48, Nonsense Mutation 9, Frame Shift Ins 8, Intron 2, Frame Shift Del 2, Splice Site 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLI3 | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121917712, CM050631, COSV67887574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 93/203 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 72/98 reads (73%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- AGO4 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1374122623, COSV64617367; called by muse, mutect2, varscan2
- ANGPTL4 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1006366989, COSV56844936; called by muse, mutect2, varscan2
- ANKDD1A | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs368863404, COSV60353565; called by muse, mutect2, varscan2
- APOB | c.10060G>T p.A3354S | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV99266662; called by muse, mutect2, varscan2
- ARID4B | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 119/219 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs781028340, COSV51604363; called by muse, mutect2, varscan2
- ATP6V1B1 | c.913T>C p.S305P | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52269864; called by muse, mutect2, varscan2
- C2orf76 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as rs780592227, COSV58347061; called by muse, mutect2, varscan2
- CACNA1E | c.1876G>T p.G626* | Nonsense Mutation (SNP) | VAF 81/186 reads (44%) | catalogued as COSV100704099; called by muse, mutect2, varscan2
- CCDC90B | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs779039037, COSV52624179; called by muse, mutect2, varscan2
- CD109 | c.3866A>G p.E1289G | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV54650600; called by muse, mutect2, varscan2
- CLSPN | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 39/118 reads (33%) | catalogued as COSV52052063; called by muse, mutect2, varscan2
- CNTN1 | c.1514C>T p.T505M | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs556601462, COSV61638909; called by muse, mutect2, varscan2
- CNTNAP5 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs775432842, COSV70482055, COSV70489649; called by muse, mutect2, varscan2
- COL18A1 | c.1460C>A p.P487Q (on ENST00000359759 / NM_130444.3; = p.P252Q on NM_030582.4) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as COSV62702650; called by muse, mutect2, varscan2
- CSE1L | c.1101G>C p.E367D | Missense Mutation (SNP) | VAF 68/488 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.654); catalogued as COSV53702394; called by muse, mutect2, varscan2
- CSE1L | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 70/489 reads (14%) | catalogued as COSV53702404; called by muse, mutect2, varscan2
- CTSF | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs180808563; called by muse, mutect2, varscan2
- CYYR1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs150622120; called by muse, mutect2, varscan2
- DAPK1 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs776122467, COSV63785215; called by muse, mutect2, varscan2
- DDX60L | c.2969C>A p.T990K | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52714774; called by muse, mutect2, varscan2
- DIO3 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100832173, COSV63773017; called by muse, mutect2, varscan2
- DNAH10 | c.1243G>A p.G415R (on ENST00000409039; = p.G354R on NM_207437.3) | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs775064137, COSV101292317, COSV68988473; called by muse, mutect2, varscan2
- DNAH3 | c.10204G>A p.A3402T | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs765445250, COSV54524923; called by muse, mutect2, varscan2
- FAM214A | c.2969G>A p.R990Q | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55924796; called by muse, mutect2, varscan2
- FAT3 | c.3434C>T p.A1145V | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV53121084; called by muse, mutect2, varscan2
- FCGRT | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs373482955; called by muse, mutect2, varscan2
- FER1L5 | c.4649G>A p.R1550Q (on ENST00000623019; = p.R1523Q on NM_001293083.2) | Missense Mutation (SNP) | VAF 60/83 reads (72%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.692); catalogued as rs745681758, COSV67606278; called by muse, mutect2, varscan2
- FMN2 | c.3131C>T p.P1044L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.028); catalogued as rs202165125, COSV100146264, COSV60426498, COSV60438124; called by muse, varscan2
- FSCB | c.641G>T p.S214I | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV61217774, COSV61218362; called by muse, mutect2, varscan2
- GPR12 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.053); catalogued as rs1343304181, COSV67344424; called by muse, mutect2
- GPR32 | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as rs879062227, COSV54514708; called by muse, mutect2, varscan2
- HAPLN2 | c.460C>G p.P154A | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV99660998; called by muse, mutect2, varscan2
- HECW1 | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs929423946, COSV67838087; called by muse, mutect2
- HERC1 | c.13732C>G p.Q4578E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV101496725; called by muse, mutect2, varscan2
- HLX | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 103/187 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1423077430, COSV65044389; called by muse, mutect2, varscan2
- HS6ST3 | c.1289A>G p.D430G | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV65010170; called by muse, mutect2, varscan2
- HTR1A | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 68/92 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1422885093, COSV60501180, COSV60502308; called by muse, mutect2, varscan2
- IGLV3-10 | c.147dup p.Y50Ifs*19 | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | catalogued as rs776773283; called by mutect2, varscan2
- IKBKB | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV60597690; called by muse, mutect2, varscan2
- IL18 | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 43/63 reads (68%) | catalogued as COSV54781735; called by muse, mutect2, varscan2
- KCTD19 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 57/81 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs370111988; called by muse, mutect2, varscan2
- LARS1 | c.319G>A p.E107K (on ENST00000394434 / NM_020117.11; = p.E80K on NM_016460.3) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50978500; called by muse, mutect2, varscan2
- LIN28A | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1464503419, COSV54262148; called by muse, mutect2, varscan2
- LMAN1L | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1471656721, COSV59004162; called by mutect2, varscan2
- MAP3K4 | c.3548C>T p.A1183V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1034822875, COSV62334551; called by muse, mutect2, varscan2
- MARK4 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.397); catalogued as rs1039550856, COSV53464813; called by muse, mutect2, varscan2
- MARS1 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 32/54 reads (59%) | catalogued as rs1197346687, COSV56255485; called by muse, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as rs750092100; called by mutect2, varscan2
- MMP25 | c.426G>T p.M142I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV100339548; called by muse, mutect2, varscan2
- MUC16 | c.37619G>T p.G12540V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.01); catalogued as COSV67471722; called by muse, mutect2, varscan2
- MYH2 | c.3061G>A p.D1021N | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1212639545, COSV55432748; called by muse, mutect2, varscan2
- NCOA6 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs532522078, COSV100750174; called by muse, mutect2, varscan2
- NIN | c.1493A>C p.E498A | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99814271; called by muse, mutect2
- NIPBL | c.2495G>T p.R832L | Missense Mutation (SNP) | VAF 108/193 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.144); catalogued as COSV99241547; called by muse, mutect2, varscan2
- NLRP2 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.693); catalogued as rs767901107, COSV54752314, COSV99672463; called by muse, mutect2, varscan2
- NLRP3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 77/117 reads (66%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as rs769647268, CM1414461, COSV60220167; called by muse, mutect2, varscan2
- NPAS3 | c.319G>A p.A107T (on ENST00000356141 / NM_001164749.2; = p.A77T on NM_022123.3) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.118); catalogued as COSV58089522; called by muse, varscan2
- NPAS3 | c.1359G>T p.E453D (on ENST00000356141 / NM_001164749.2; = p.E421D on NM_022123.3) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); catalogued as COSV60838665; called by muse, mutect2, varscan2
- OBSCN | c.4283G>A p.R1428Q | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.169); catalogued as rs758707780, COSV52741468; called by muse, mutect2, varscan2
- OR10A2 | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100225109; called by muse, mutect2, varscan2
- OR10C1 | c.194G>A p.R65H (on ENST00000622521; = p.R63H on NM_013941.3) | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.828); catalogued as rs779708085, COSV65823122, COSV65823353; called by muse, mutect2, varscan2
- OR3A2 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.246); catalogued as rs1048613178, COSV101375063; called by mutect2, varscan2
- OR51S1 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as rs200652284, COSV59057683; called by muse, mutect2, varscan2
- OTOF | c.5374C>T p.R1792C (on ENST00000272371 / NM_194248.3; = p.R1025C on NM_004802.4) | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs142111099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OTOGL | c.5621G>A p.R1874H (on ENST00000547103; = p.R1865H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs753442888, COSV54013201; called by muse, mutect2, varscan2
- PAQR9 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as rs1245004764, COSV61418351; called by muse, mutect2, varscan2
- PCDHA10 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 161/226 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV56479731, COSV56488368; called by muse, mutect2, varscan2
- PCDHA2 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.287); catalogued as COSV65365430; called by muse, mutect2, varscan2
- PCDHGA8 | c.940T>C p.F314L | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.073); catalogued as COSV53963278; called by muse, mutect2, varscan2
- PDGFRA | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as rs1308521786, COSV57268909, COSV57269165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEMT | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs756474306, COSV55131771; called by muse, mutect2, varscan2
- PIN1 | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56112790; called by muse, mutect2, varscan2
- PKD2L1 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs777495778, COSV58396432; called by muse, mutect2, varscan2
- PLCZ1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as rs751593977, COSV56853692; called by muse, mutect2, varscan2
- PNPLA2 | c.425A>G p.N142S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.348); catalogued as rs758738508, COSV60744447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PREX2 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs200682883, COSV55757236, COSV55764910; called by muse, mutect2, varscan2
- QRFPR | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 102/159 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0.083); catalogued as rs1239344940, COSV57677657; called by muse, mutect2, varscan2
- RFC5 | c.926+1G>A p.X309_splice | Splice Site (SNP) | VAF 30/191 reads (16%) | catalogued as COSV57477825; called by muse, mutect2, varscan2
- RNF168 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as COSV58836717, COSV58839835; called by muse, mutect2, varscan2
- SCN5A | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs199473093, CM065458, COSV100346312, COSV100349494; ClinVar: uncertain significance; called by muse, mutect2
- SEMA4G | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761554973, COSV52968917; called by muse, mutect2, varscan2
- SERINC3 | c.863C>A p.S288Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54857081; called by muse, mutect2, varscan2
- SPHKAP | c.3628G>T p.A1210S | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs1464552392, COSV60882122; called by muse, mutect2, varscan2
- SPOPL | c.735T>G p.D245E | Missense Mutation (SNP) | VAF 211/431 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54513921; called by muse, mutect2, varscan2
- ST18 | c.2512T>C p.S838P | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52496577; called by muse, mutect2, varscan2
- STRIP2 | c.1260G>A p.W420* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV50808375; called by muse, mutect2
- STRIP2 | c.1698C>G p.H566Q | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV50804899; called by muse, mutect2, varscan2
- STUB1 | c.613-1G>T p.X205_splice | Splice Site (SNP) | VAF 20/98 reads (20%) | catalogued as COSV50198309; called by muse, mutect2, varscan2
- STUM | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64684422; called by muse, mutect2, varscan2
- SYNE1 | c.11905A>G p.M3969V (on ENST00000367255 / NM_182961.4; = p.M3898V on NM_033071.3) | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99572107; called by muse, mutect2, varscan2
- TENM3 | c.7087C>T p.R2363W | Missense Mutation (SNP) | VAF 80/120 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs757494710, COSV101305270; called by muse, mutect2, varscan2
- TFAP2C | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as rs150059207, COSV99571385; called by muse, mutect2, varscan2
- TLN1 | c.4558A>G p.T1520A | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59208225; called by muse, mutect2, varscan2
- TNRC6B | c.3673C>T p.R1225W (on ENST00000454349 / NM_001162501.2; = p.R1115W on NM_015088.3) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57291470; called by muse, mutect2, varscan2
- TSN | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67605478; called by muse, mutect2, varscan2
- UNC13C | c.2561C>T p.T854M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.649); catalogued as rs375077921, COSV52882984; called by muse, mutect2, varscan2
- URGCP | c.1742G>A p.R581Q (on ENST00000453200 / NM_001077663.3; = p.R572Q on NM_017920.4) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.253); catalogued as rs774012630, COSV56248451; called by muse, mutect2, varscan2
- UTRN | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs368046583; called by muse, mutect2, varscan2
- XIRP1 | c.3158C>T p.A1053V | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV61138959; called by muse, mutect2, varscan2
- ZMAT4 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1419897637, COSV52695626; called by muse, mutect2, varscan2
- ZNF134 | c.902C>A p.S301Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV68696421; called by muse, mutect2, varscan2
- ZNF189 | c.759T>G p.I253M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99407253; called by muse, mutect2, varscan2
- ZNF280B | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs775765845, COSV64528312, COSV64528706; called by muse, mutect2, varscan2
- ZNF331 | c.1073C>A p.T358K | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1292047576, COSV53477343; called by muse, mutect2, varscan2
- ZNF439 | c.1360C>T p.R454* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as rs201514573; called by muse, mutect2, varscan2
- ZSCAN5B | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs1244662861, COSV62839744; called by muse, mutect2, varscan2
- AC245033.1 | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 130/241 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ASPM | c.5615dup p.L1872Ffs*24 | Frame Shift Ins (INS) | VAF 42/121 reads (35%) | called by mutect2, pindel, varscan2
- C6 | c.1810dup p.E604Gfs*23 | Frame Shift Ins (INS) | VAF 61/119 reads (51%) | called by mutect2, pindel, varscan2
- CEP162 | c.2055dup p.Q686Tfs*11 | Frame Shift Ins (INS) | VAF 61/200 reads (31%) | called by mutect2, pindel, varscan2
- IGHV3OR16-8 | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 90/120 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- NOSTRIN | c.572dup p.N191Kfs*36 (on ENST00000317647 / NM_001039724.4; = p.N113Kfs*36 on NM_052946.3) | Frame Shift Ins (INS) | VAF 46/310 reads (15%) | called by mutect2, varscan2
- SHROOM3 | c.4807dup p.T1603Nfs*9 | Frame Shift Ins (INS) | VAF 83/162 reads (51%) | called by mutect2, pindel, varscan2
- TGIF1 | c.605_606dup p.G203Lfs*32 (on ENST00000330513 / NM_001374396.1; = p.G223Lfs*32 on NM_003244.4) | Frame Shift Ins (INS) | VAF 12/15 reads (80%) | called by mutect2, varscan2
- VPS13B | c.11961dup p.S3988Lfs*4 | Frame Shift Ins (INS) | VAF 74/173 reads (43%) | called by mutect2, pindel, varscan2
- ADGRE1 | c.1152T>G p.L384= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV51676522; called by muse, varscan2
- ADGRG7 | c.1092C>T p.D364= | Silent (SNP) | VAF 64/106 reads (60%) | catalogued as COSV56297463; called by muse, varscan2
- ANO1 | c.981G>A p.K327= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV60285643; called by muse, mutect2, varscan2
- ASB4 | c.408C>T p.Y136= | Silent (SNP) | VAF 35/151 reads (23%) | catalogued as rs747253499, COSV57508154; called by muse, mutect2, varscan2
- BRIP1 | c.2232C>T p.D744= | Silent (SNP) | VAF 51/243 reads (21%) | catalogued as rs374362388; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- CDH19 | c.648G>T p.L216= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV50960874; called by muse, mutect2, varscan2
- CDH4 | c.537C>T p.P179= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as rs774837151, COSV64657693; called by muse, mutect2, varscan2
- CHST2 | c.717C>T p.S239= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV58885862; called by muse, mutect2, varscan2
- CPLANE1 | c.8760G>T p.G2920= | Silent (SNP) | VAF 164/250 reads (66%) | catalogued as rs370013757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSPG4 | c.3327C>T p.D1109= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs778413411, COSV57896351; called by muse, mutect2, varscan2
- CYP21A2 | c.1173C>T p.G391= | Silent (SNP) | VAF 56/292 reads (19%) | catalogued as rs770449904, COSV100926451; called by muse, mutect2, varscan2
- DYRK1A | c.477C>T p.Y159= | Silent (SNP) | VAF 55/111 reads (50%) | catalogued as rs1049773; ClinVar: likely benign; called by muse, mutect2, varscan2
- EGR4 | c.990C>T p.A330= (on ENST00000545030; = p.A227= on NM_001965.4) | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs1558599823, COSV71531878; called by muse, mutect2, varscan2
- ELFN2 | c.573C>T p.C191= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs145251233; called by muse, mutect2, varscan2
- EPHA6 | c.2671C>A p.R891= (on ENST00000389672 / NM_001080448.3; = p.R283= on NM_173655.4) | Silent (SNP) | VAF 56/117 reads (48%) | catalogued as COSV101064324, COSV67598944; called by muse, mutect2, varscan2
- FLCN | c.1290G>A p.V430= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV53259883; called by muse, mutect2, varscan2
- GPR88 | c.147C>T p.N49= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs367783203; called by muse, mutect2, varscan2
- HHIPL2 | c.1872G>A p.P624= | Silent (SNP) | VAF 54/152 reads (36%) | catalogued as rs749643311, COSV58563398; called by muse, mutect2, varscan2
- HIF1A | c.1548C>A p.P516= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV60189536; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1674C>T p.C558= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs754262196, COSV58022293; called by muse, mutect2
- KRTAP13-1 | c.258C>A p.S86= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV62663508; called by muse, mutect2, varscan2
- MDGA2 | c.1437G>A p.T479= (on ENST00000399232 / NM_001113498.2; = p.T181= on NM_182830.4) | Silent (SNP) | VAF 48/79 reads (61%) | catalogued as rs776675809, COSV100638842, COSV62096103; called by muse, mutect2, varscan2
- MUC16 | c.26403C>T p.T8801= | Silent (SNP) | VAF 134/309 reads (43%) | catalogued as rs1460072358, COSV67471725; called by muse, mutect2, varscan2
- NT5M | c.345C>T p.V115= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV66518969; called by muse, mutect2, varscan2
- OTUD7A | c.669C>T p.H223= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs765724002, COSV100192431, COSV61037805; called by muse, mutect2, varscan2
- PAPPA | c.4737C>T p.D1579= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as rs140928157; called by muse, mutect2, varscan2
- PCDHA11 | c.1224G>T p.L408= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as COSV56509759; called by muse, mutect2, varscan2
- PCDHAC2 | c.720G>A p.T240= | Silent (SNP) | VAF 58/84 reads (69%) | catalogued as rs782309199, COSV53853158; called by muse, mutect2
- PCDHB8 | c.666C>A p.P222= | Silent (SNP) | VAF 56/902 reads (6%) | catalogued as COSV99177163; called by muse, mutect2
- PEG3 | c.1524G>A p.K508= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs141314845, COSV99032395; called by mutect2, varscan2
- PLPPR3 | c.123G>T p.L41= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV100608876; called by muse, mutect2, varscan2
- POU3F4 | c.393C>A p.L131= | Silent (SNP) | VAF 114/120 reads (95%) | catalogued as COSV64539311; called by muse, mutect2, varscan2
- PRMT7 | c.663C>T p.G221= | Silent (SNP) | VAF 39/57 reads (68%) | catalogued as rs531083026, COSV59833776; called by muse, mutect2, varscan2
- PRX | c.1293G>T p.G431= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV52530507; called by muse, mutect2, varscan2
- RHOV | c.600G>A p.S200= | Silent (SNP) | VAF 45/74 reads (61%) | catalogued as rs1363961922, COSV99592125; called by muse, mutect2, varscan2
- S1PR3 | c.972C>T p.R324= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs201820975; called by muse, mutect2, varscan2
- SLC12A3 | c.1947G>A p.T649= | Silent (SNP) | VAF 34/55 reads (62%) | catalogued as rs151041573, COSV52635287, COSV99344604; called by muse, mutect2, varscan2
- STAB2 | c.5418G>A p.K1806= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV66340428; called by muse, mutect2, varscan2
- SYNE1 | c.24162G>A p.T8054= (on ENST00000367255 / NM_182961.4; = p.T7983= on NM_033071.3) | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs185088779; ClinVar: likely benign / uncertain significance / benign; called by muse, mutect2, varscan2
- TPR | c.603G>A p.L201= | Silent (SNP) | VAF 55/112 reads (49%) | catalogued as COSV66602013; called by muse, mutect2, varscan2
- TRIM15 | c.777C>T p.D259= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100938878; called by muse, mutect2, varscan2
- TSHZ3 | c.2766C>T p.Y922= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV53673393; called by muse, mutect2, varscan2
- UFL1 | c.2352C>G p.L784= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as rs542194906, COSV65149984; called by muse, mutect2, varscan2
- UNC79 | c.7780C>T p.L2594= (on ENST00000393151 / NM_001346218.2; = p.L2417= on NM_020818.5) | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs1181167261, COSV56391585; called by muse, mutect2, varscan2
- WNT2B | c.582C>T p.Y194= (on ENST00000369684 / NM_024494.3; = p.Y175= on NM_004185.4) | Silent (SNP) | VAF 60/101 reads (59%) | catalogued as rs149716293; called by muse, mutect2, varscan2
- ZFHX4 | c.4311C>T p.F1437= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as COSV50962726; called by muse, mutect2, varscan2
- ZIC4 | c.876G>A p.P292= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV67172169, COSV67173311; called by muse, mutect2, varscan2
- ZNF846 | c.1545C>T p.F515= | Silent (SNP) | VAF 87/200 reads (44%) | catalogued as COSV101194358; called by muse, mutect2, varscan2
- FAM184A | c.159+9020G>A | Intron (SNP) | VAF 44/182 reads (24%) | catalogued as rs367701690, COSV58856359; called by muse, mutect2, varscan2
- SHC1 | c.1624-352G>A | Intron (SNP) | VAF 24/43 reads (56%) | called by muse, mutect2, varscan2
- ZNF862 | chr7:149833825 G>A | 5'Flank (SNP) | VAF 23/35 reads (66%) | catalogued as COSV56224279; called by muse, mutect2, varscan2
